Gene-level copy-number profile of tumor specimen ALCH-AENH-TTP1-A from ALCHEMIST case ALCH-AENH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.6 years (25,431 days).
Specimen ALCH-AENH-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 72247283-e5fe-4ce7-a937-a6803ca06bbc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AENH-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/31c75dfe-dde0-4d51-aa42-4891564b876c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 549; copy number 1: 4,879; copy number 2: 52,450; copy number 3: 1,010; copy number 4: 8; copy number 5: 1; copy number 8: 6.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:1,050,384–1,112,063, 2 genes (within-gene range 0–3): SLC12A7, MIR4635.
- chr8:143,579,697–143,599,541, 1 gene (within-gene range 0–2): EEF1D.
- chr12:57,128,483–57,240,715, 7 genes (within-gene range 0–2): LRP1, LRP1-AS, MIR1228, NXPH4, AC137834.2, SHMT2, NDUFA4L2.
- chr14:104,690,091–104,691,284, 1 gene (within-gene range 0–2): AL583722.3.
- chr16:1,770,286–1,794,971, 6 genes (within-gene range 0–3): NME3, MRPS34, EME2, SPSB3, NUBP2, IGFALS.
- chr17:2,712,309–2,749,504, 3 genes (within-gene range 0–2): AC005696.1, AC005696.4, CCDC92B.
- chr17:29,560,547–29,567,037, 1 gene (within-gene range 0–2): ABHD15.
- chr17:29,566,052–29,614,761, 5 genes (within-gene range 0–2): TP53I13, AC104564.3, GIT1, ANKRD13B, AC104564.4.
- chr17:82,078,338–82,098,294, 1 gene: FASN.
- chr20:63,540,810–63,574,239, 4 genes: SRMS, AL121829.2, FNDC11, HELZ2.
- chr22:20,198,729–20,208,524, 2 genes: AC007663.2, LINC00896.
- chr22:24,251,828–24,265,525, 2 genes: POM121L9P, BCRP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:89,295–133,723, 1 gene, copy number 8 (within-gene range 1–8): AL627309.1.
- chr1:131,025–157,887, 5 genes, copy number 8: CICP27, AL627309.6, AL627309.7, AL627309.2, RNU6-1100P.
- chr11:135,061,781–135,075,908, 1 gene, copy number 5: LINC02684.

Autosomal genes at a single copy (total copy number 1): 3,150. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
